CCDI case PBCRCF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/373d7d72-fd38-414d-a78c-3479cbedaba5

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Spindle cell rhabdomyosarcoma: ICD-O-3 morphology code: 8912/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of thorax; Age at diagnosis: 10.4 years (3,812 days).

Biospecimens (3 samples)
- Sample 0DX7EX: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DX7F8, 0DX7FX (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
